Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAXB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAXB-01A (Primary Tumor).

[page 1 of 3]
UUID:AB550C0A-6FE6-4D92-ASE3-A7141A32CC26

ACCT#: [REDACTED] DOB: [REDACTED]

Specimen #: [REDACTED] Dr: [REDACTED]
Date Obtained: [REDACTED] Date Received: [REDACTED] Date Printed: [REDACTED]

CLINICAL HISTORY:

ICD-9: 233.1; [REDACTED] - CXBX: INV CARCINOMA; [REDACTED] : ADENOCARCINOMA

SPECIMEN/PROCEDURE:

1. CERVIX -
2. CERVIX -

IMPRESSION:

- 1) CERVICAL BIOPSY AT 6 O'CLOCK; *- See attach path discrepancy form.*
Poorly differentiated carcinoma with focal glandular differentiation (see comment).
- 2) CERVICAL BIOPSY FOR
Poorly differentiated carcinoma with focal glandular differentiation.

Dictated by: [REDACTED]
Entered: [REDACTED]

COMMENT:

This tumor has an unusual pattern with a solid, geographic growth pattern infiltrating the stroma. In some areas definite gland lumina are identified. There is little or no mucin production. Apoptosis is prominent. Special stained performed on the previous specimen support cervical primary, but do not definitively distinguish a cell type. Adenocarcinoma is favored but poorly differentiated adenosquamous carcinoma is in the differential diagnosis.

Entered: [REDACTED]

GROSS DESCRIPTION:

1. Received in formalin labeled the patient's name and 6 o'clock. Received is a pale pink to red tan irregular tissue fragment that is 1.1 x 1 x 0.4 cm. Specimen is entirely submitted in cassette #1.
2. Received in formalin labeled the patient's name and [REDACTED]. Received are 2 pink to pale tan tissue fragments ranging from 0.6-1 cm in greatest dimension. Specimen is entirely submitted in cassette #2.

Dictated by: [REDACTED]
Entered: [REDACTED]

Patient: [REDACTED] Age/Sex: [REDACTED] /F Acct# [REDACTED] Uni [REDACTED]

ABLE
ICD: C33
with
Adenocarcinoma, endocervical type 8384/3
(Carcinoma) NOS 8010/3
Site Cervix NOS C53.9
no 6/3/14

[page 2 of 3]
Specimen #:

DOB:
Obtained:

(Continued) Page: 2

CPT Codes:
CERVICAL BIOPSY/88305/2

ICD9 Codes:
180.9

Electronically Signed by [REDACTED]

*Per TSS dx discrepancy form, T6A
tumor is adenocarcinoma of
endocervical type.*

Patient: [REDACTED] Age/Sex: /F Acct# [REDACTED] Unit# [REDACTED]

Reviewer Initials: [REDACTED]	Date Reviewed: 3/14/14	

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name) _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Poorly diff carcinoma with focal glandular differentiation	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Endocervical type of adenocarcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Diagnosis verified as: Endocervical adenocarcinoma of usual type.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file bd29ebee-fcaa-4117-9d68-a54329474125 (TCGA-ZJ-AAXB.AB550C0A-6FE6-4D92-A5E3-A7141A32CC26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).